Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LS, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LS-01A (Primary Tumor).

ICD-6-3
Carcinoma, adrenal cortical
8370/3

Site: (R) Adrenal Gland cortex
C74.0

9/10 2/6/13

Procedure: Right adrenalectomy

Gross description: tumor is 208g; measuring 9.3 x 8.7 x 5.5cm.

Diagnosis: Based on paper from Bisceglia et al, this tumor is consistent with adrenal cortical carcinoma. Weiss score = 6. Chronic cholecystitis, colculosis (s/p cholecystectomy).

Site Discrepancy		

Source: NCI Genomic Data Commons file 0dde2fee-d917-4811-8172-3e22518e7eed (TCGA-OR-A5LS.31004530-E017-4913-A8AA-7AE709EAE0F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).